Somatic mutation profile of tumor specimen TCGA-HT-7602-01A (aliquot TCGA-HT-7602-01A-21D-2086-08) from TCGA case TCGA-HT-7602, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 21.8 years (7,946 days).
Specimen TCGA-HT-7602-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc538739-0557-4a97-b6fe-7e9b3320aa0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7602-10A (Blood Derived Normal), aliquot TCGA-HT-7602-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4da007fa-5909-484c-b9e3-3fdf712ec748

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/130 reads (22%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACACB | c.3370G>A p.G1124S | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs567554237, COSV58143105; called by muse, mutect2
- MPEG1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV57093907; called by muse, mutect2
- NAT2 | c.399G>C p.Q133H | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV54062978; called by muse, mutect2, varscan2
- NCKAP1L | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs375305246; called by muse, mutect2, varscan2
- PPP2R2D | c.531T>G p.I177M | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as COSV70778607; called by muse, mutect2, varscan2
- ADAMTS12 | c.3666C>T p.P1222= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV61256861, COSV61274230; called by muse, mutect2
